Somatic mutation profile of tumor specimen TCGA-SJ-A6ZI-01A (aliquot TCGA-SJ-A6ZI-01A-12D-A34Q-09) from TCGA case TCGA-SJ-A6ZI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 64.8 years (23,653 days).
Specimen TCGA-SJ-A6ZI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bba8d574-e73d-4709-8391-b52339cd4c16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SJ-A6ZI-10B (Blood Derived Normal), aliquot TCGA-SJ-A6ZI-10B-01D-A34Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bab43bab-c9a0-4b5d-8525-2ec6c21f4cf0

The open-access MAF lists 1,652 somatic variants for this specimen: 1,161 protein-altering or splice-affecting, 457 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 998, Silent 457, Nonsense Mutation 61, Frame Shift Del 44, Splice Site 21, Frame Shift Ins 19, Intron 14, Splice Region 14, RNA 8, 3'UTR 6, 3'Flank 3, In Frame Del 2.

Variants (750 of 1,652; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5527C>T p.R1843W | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs62642576, CM990066; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADA | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs121908737, CM900005, COSV100866648; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- ALB | c.79+1G>A p.X27_splice | Splice Site (SNP) | VAF 15/76 reads (20%) | catalogued as rs77408163, CS020325; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL10 | c.136dup p.I46Nfs*4 | Frame Shift Ins (INS) | VAF 10/25 reads (40%) | catalogued as rs387906351; ClinVar: pathogenic; called by mutect2, varscan2
- COL5A1 | c.3752del p.P1251Rfs*25 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs786205100; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- CYP21A2 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs9378251, CM920227, CM994449; ClinVar: pathogenic; called by mutect2, varscan2
- EIF2B1 | c.252+1G>A p.X84_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as rs113994006, CS023203; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 24/89 reads (27%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- PKD2 | c.1094+1G>A p.X365_splice | Splice Site (SNP) | VAF 8/45 reads (18%) | catalogued as rs58606740, CS065606, CS1110577, COSV52940349; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by mutect2, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SZT2 | c.6724C>T p.R2242W (on ENST00000634258 / NM_001365999.1; = p.R2185W on NM_015284.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765848129, COSV100987685; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TMEM200C | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs374225402; called by muse, mutect2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- AAK1 | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.781); catalogued as rs1423773467, COSV101275961, COSV101276040; called by muse, mutect2, varscan2
- AAK1 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV101117271; called by muse, mutect2, varscan2
- ABCA7 | c.5864G>A p.G1955D | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373283316, COSV99566702; called by muse, mutect2, varscan2
- ABCB6 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759447077, COSV54696551; called by muse, mutect2, varscan2
- ABCB7 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs750841532, COSV99504578; called by muse, mutect2, varscan2
- ABCC1 | c.3874C>T p.R1292* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as rs374116688; called by muse, mutect2, varscan2
- ABCC11 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100751164; called by muse, mutect2, varscan2
- ABTB2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs773380107, COSV100132197; called by muse, mutect2, varscan2
- AC093525.2 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | PolyPhen benign (0.429); catalogued as COSV53551700; called by muse, mutect2, varscan2
- AC127029.3 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.266); catalogued as rs768782282, COSV100033363; called by muse, mutect2, varscan2
- ACKR1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV100929671; called by muse, mutect2
- ACSS2 | c.2066T>C p.I689T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs760294223, COSV99404618; called by muse, mutect2, varscan2
- ACTB | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as COSV100079969; called by muse, mutect2, varscan2
- ACTL7B | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV101012494; called by muse, mutect2, varscan2
- ACTN1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs773643865, COSV51993429; called by muse, mutect2, varscan2
- ACVR1 | c.1331T>C p.M444T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1485718076, COSV99718147; called by muse, mutect2, varscan2
- ACVR2B | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752442546, COSV100754419; called by muse, varscan2
- ACY3 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.365); catalogued as rs1381952209, COSV99663173; called by muse, mutect2, varscan2
- ADA2 | c.321A>G p.K107= | Splice Region (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99376507; called by muse, mutect2, varscan2
- ADAM29 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV63665264; called by muse, mutect2, varscan2
- ADAMTS16 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs888665824, COSV99943143; called by muse, mutect2, varscan2
- ADAMTS20 | c.4918G>A p.V1640M | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV101238657, COSV67136294; called by muse, mutect2, varscan2
- ADARB2 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs779363940, COSV101187355; called by muse, mutect2, varscan2
- ADCY8 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs764060103, COSV53897935, COSV99654522; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.578T>G p.F193C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100416982; called by mutect2, varscan2
- ADGRA3 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750505698, COSV51561810; called by muse, mutect2, varscan2
- ADGRB1 | c.3656C>T p.A1219V | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.188); catalogued as COSV100030422; called by muse, mutect2, varscan2
- ADGRB3 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV101001884, COSV101002015; called by muse, mutect2, varscan2
- ADGRF5 | c.2503G>T p.A835S | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as COSV99346479; called by muse, mutect2, varscan2
- ADGRL2 | c.3934G>A p.D1312N (on ENST00000370717 / NM_001366005.1; = p.D1256N on NM_012302.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as rs200831885, COSV99591706; called by muse, mutect2, varscan2
- ADRA2A | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746155867, COSV54530057; called by muse, mutect2, varscan2
- AFG3L2 | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs528206939, COSV99302206; called by muse, mutect2, varscan2
- AGO2 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99596475; called by muse, mutect2, varscan2
- AHCTF1 | c.6554A>G p.Q2185R (on ENST00000366508; = p.Q2159R on NM_015446.5) | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100404470; called by muse, mutect2, varscan2
- AHNAK2 | c.9664C>A p.L3222I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.995); catalogued as COSV100319040; called by muse, mutect2, varscan2
- AJAP1 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65454692, COSV65455821; called by muse, mutect2, varscan2
- AK7 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs982939189, COSV99967565; called by muse, mutect2, varscan2
- AKAP6 | c.6154G>A p.E2052K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs763648995, COSV99804646; called by muse, mutect2, varscan2
- AKAP7 | c.981G>T p.E327D (on ENST00000431975 / NM_016377.4; = p.E60D on NM_004842.4) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99541819; called by muse, mutect2, varscan2
- AKAP9 | c.4032A>T p.E1344D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV100663154; called by muse, mutect2, varscan2
- ALAS2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM095122, CM109565, COSV100238421, COSV100238671; called by muse, mutect2, varscan2
- ALDH18A1 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745614904, COSV100973306; called by muse, mutect2, varscan2
- ALDH3B1 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs755218225; called by muse, mutect2, varscan2
- ALDH3B1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs753775480, COSV50288369; called by muse, mutect2, varscan2
- ALKAL2 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100732647; called by muse, mutect2, varscan2
- ALLC | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.822); catalogued as COSV99378303; called by muse, mutect2, varscan2
- ALMS1 | c.11819C>A p.T3940N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.34); catalogued as COSV100043848; called by muse, mutect2, varscan2
- AMY2A | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 72/668 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101340634, COSV101340678; called by mutect2, varscan2
- ANK3 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV55055672; called by muse, mutect2, varscan2
- ANKRD23 | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100450550; called by muse, mutect2, varscan2
- ANO1 | c.2089C>T p.Q697* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100304519; called by muse, mutect2, varscan2
- ANO10 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs144728237, COSV52730851; called by mutect2, varscan2
- AP2A1 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as rs749773354, COSV100756525; called by muse, mutect2, varscan2
- APOBEC3B | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs113792154; called by muse, mutect2, varscan2
- APOBEC3D | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs752483265, COSV99329204; called by muse, mutect2, varscan2
- APOL3 | c.893T>G p.I298S (on ENST00000349314 / NM_145640.2; = p.I227S on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100652172; called by muse, mutect2, varscan2
- APP | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs201094604, COSV100695891; called by muse, mutect2, varscan2
- ARAP3 | c.3074G>A p.R1025Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs777602219, COSV53349693; called by muse, mutect2, varscan2
- ARF1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99683356; called by muse, mutect2, varscan2
- ARFGEF3 | c.5100A>C p.K1700N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as COSV99294778; called by muse, mutect2, varscan2
- ARHGAP10 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs200388255, COSV60600471; called by muse, mutect2, varscan2
- ARHGAP20 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV99505448; called by muse, mutect2, varscan2
- ARHGAP4 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as rs201193891, COSV61687206; called by muse, mutect2, varscan2
- ARHGAP5 | c.902C>A p.P301H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV61539422, COSV61539506; called by muse, mutect2, varscan2
- ARHGEF10L | c.3685G>A p.D1229N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs1464577278, COSV51428663, COSV99393886; called by muse, mutect2
- ARHGEF26 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV62845345; called by muse, mutect2, varscan2
- ARHGEF37 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs770631740, COSV100382318, COSV61368397; called by muse, mutect2, varscan2
- ARID1A | c.3219G>A p.W1073* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV61375653; called by muse, mutect2, varscan2
- ARID1B | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99272389; called by muse, mutect2, varscan2
- ARID4B | c.3376G>T p.G1126* | Nonsense Mutation (SNP) | VAF 28/72 reads (39%) | catalogued as COSV99936391; called by muse, mutect2, varscan2
- ARL1 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99880403; called by muse, mutect2, varscan2
- ARPP21 | c.1451C>A p.P484Q | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV99491327, COSV99493445; called by muse, mutect2, varscan2
- ARSJ | c.1292del p.N431Mfs*86 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs1562327720; called by mutect2, pindel, varscan2
- ASB16 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs371424418; called by muse, mutect2, varscan2
- ASB9 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 36/124 reads (29%) | catalogued as COSV100995592; called by muse, mutect2, varscan2
- ASIC2 | c.1437+1G>A p.X479_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99859306; called by muse, mutect2, varscan2
- ASXL2 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV99712065; called by muse, mutect2, varscan2
- ASXL3 | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV99326749; called by muse, mutect2, varscan2
- ATF6B | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as COSV100913614; called by muse, mutect2, varscan2
- ATG9A | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs377367353; called by muse, mutect2, varscan2
- ATIC | c.1278G>C p.K426N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99378222; called by muse, mutect2, varscan2
- ATP10A | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749423426, COSV100791389, COSV63513932; called by muse, mutect2, varscan2
- ATP13A4 | c.716T>C p.L239S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.817); catalogued as COSV99795289; called by muse, mutect2, varscan2
- ATP2A1 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs201798363, COSV62870624; called by muse, mutect2, varscan2
- ATP4A | c.2920G>A p.V974I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1360565062, COSV99383113; called by muse, mutect2, varscan2
- ATP6V1B1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555708728, COSV52270451; called by muse, mutect2, varscan2
- ATP6V1C1 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV101215165; called by muse, mutect2, varscan2
- ATP6V1G2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs1278284083, COSV100385484; called by muse, mutect2, varscan2
- ATP7A | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782603364, COSV58454039; called by muse, mutect2
- ATP8A2 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99684523; called by muse, mutect2, varscan2
- ATP9A | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV100125669; called by muse, mutect2, varscan2
- AVIL | c.881T>C p.V294A | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV57681843; called by muse, mutect2, varscan2
- AVL9 | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs750180870, COSV100594810; called by muse, mutect2
- AXL | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as COSV99997308; called by muse, mutect2, varscan2
- B3GNT4 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.68); catalogued as COSV57336132, COSV99928404; called by muse, mutect2, varscan2
- B4GALT6 | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.637); catalogued as COSV99380375; called by muse, mutect2, varscan2
- BACH1 | c.842A>G p.E281G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99728744; called by muse, mutect2, varscan2
- BAG6 | c.3212G>A p.R1071Q (on ENST00000676571; = p.R1024Q on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767009688, COSV99277656; called by muse, mutect2, varscan2
- BCAR1 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.773); catalogued as COSV99366630; called by muse, mutect2, varscan2
- BCAS1 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs555168043, COSV65086426; called by muse, mutect2, varscan2
- BCKDK | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.409); catalogued as rs374568685; called by muse, mutect2, varscan2
- BCL7B | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV99790403; called by muse, mutect2, varscan2
- BDKRB2 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs201166893; called by muse, mutect2, varscan2
- BEND2 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.231); catalogued as COSV101192226, COSV66217067; called by muse, mutect2, varscan2
- BEND4 | c.740G>T p.R247M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101549801; called by muse, mutect2, varscan2
- BEND5 | c.744C>T p.S248= | Splice Region (SNP) | VAF 8/20 reads (40%) | catalogued as rs12090576; called by muse, mutect2
- BFAR | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs11546304; called by muse, mutect2, varscan2
- BID | c.257T>C p.L86P (on ENST00000317361 / NM_197966.2; = p.L40P on NM_001196.4) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100433877; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3681+1G>C p.X1227_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100863956; called by muse, mutect2, varscan2
- BMP1 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs759325498, COSV100110170; called by muse, mutect2, varscan2
- BOD1L1 | c.2204C>T p.S735L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as rs781209740, COSV99240483; called by muse, mutect2, varscan2
- BPIFB4 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.412); catalogued as rs753678971, COSV64951142; called by mutect2, varscan2
- BRD1 | c.2837T>C p.L946P (on ENST00000216267 / NM_001349940.1; = p.L1077P on NM_001304808.3) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99350347; called by muse, mutect2, varscan2
- BRD7 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101165069; called by muse, mutect2, varscan2
- BSDC1 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140093699, COSV100345137; called by muse, mutect2, varscan2
- BSN | c.5756C>T p.P1919L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs750356978, COSV99609916; called by muse, mutect2, varscan2
- BTK | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV58119730; called by muse, mutect2, varscan2
- C10orf82 | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV65024481; called by muse, mutect2, varscan2
- C11orf87 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV59356192; called by muse, mutect2, varscan2
- C16orf72 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781070790, COSV59915931; called by muse, mutect2, varscan2
- C1QTNF3 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99180734; called by muse, mutect2, varscan2
- C1orf189 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as rs747273912, COSV100634326; called by muse, mutect2, varscan2
- C2orf68 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV100108341; called by muse, mutect2, varscan2
- CA10 | c.666A>G p.I222M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV99565275; called by muse, mutect2, varscan2
- CA8 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs906750876, COSV58771378; called by muse, mutect2
- CACNA1C | c.1601T>C p.V534A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100222512; called by muse, mutect2, varscan2
- CACNG8 | c.610T>C p.W204R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99555184; called by muse, mutect2, varscan2
- CACTIN | c.1945G>A p.V649M | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698897; called by muse, mutect2, varscan2
- CAMK4 | c.592A>G p.M198V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100000370; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN15 | c.2519C>T p.A840V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV99562845; called by muse, mutect2
- CAPZA3 | c.569T>G p.F190C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.526); catalogued as COSV99857040; called by muse, mutect2, varscan2
- CARD10 | c.3016G>A p.G1006S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.916); catalogued as rs1008908544, COSV99325400; called by muse, mutect2
- CARD14 | c.751C>A p.L251M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100712625; called by muse, mutect2, varscan2
- CASP1 | c.1207G>T p.G403* (on ENST00000436863 / NM_033292.4; = p.G382* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99508126; called by muse, mutect2, varscan2
- CATSPERD | c.218dup p.T74Hfs*4 | Frame Shift Ins (INS) | VAF 28/42 reads (67%) | catalogued as rs1305833783; called by mutect2, varscan2
- CBLB | c.1685C>A p.P562H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.594); catalogued as COSV51437356, COSV99914406; called by muse, mutect2, varscan2
- CBLB | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV99914412; called by muse, mutect2
- CBLL1 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.347); catalogued as COSV99755969; called by muse, mutect2, varscan2
- CBLN2 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.221); catalogued as COSV99504662; called by muse, mutect2, varscan2
- CCDC125 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs745493733, COSV67287659; called by muse, mutect2, varscan2
- CCDC144A | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.051); catalogued as rs2928657, COSV100502212; called by mutect2, varscan2
- CCDC172 | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs766286879, COSV100320021; called by muse, mutect2, varscan2
- CCDC22 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs201088755, COSV100879914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC3 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.607); catalogued as rs1167314594, COSV101121767; called by muse, mutect2, varscan2
- CCDC40 | c.2014G>A p.G672S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as rs769532664, COSV100884335; called by muse, mutect2, varscan2
- CCDC73 | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV100068368; called by muse, mutect2, varscan2
- CCIN | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as rs368073473, COSV58724976; called by muse, mutect2, varscan2
- CCNB3 | c.2412G>A p.M804I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52074816; called by muse, mutect2, varscan2
- CCNT1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs757269550, COSV99980919; called by mutect2, varscan2
- CCNYL1 | c.440T>C p.L147S (on ENST00000295414 / NM_001330218.2; = p.L77S on NM_152523.2) | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV99776094; called by muse, mutect2, varscan2
- CCT6A | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs764432664, COSV51905472; called by muse, mutect2, varscan2
- CCT8L2 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV100743157; called by muse, mutect2, varscan2
- CD1D | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs755775062, COSV100939663; called by muse, varscan2
- CD48 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs146912720; called by mutect2, varscan2
- CD59 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as rs759088791, COSV100681318; called by mutect2, varscan2
- CD5L | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.377); catalogued as COSV100941199, COSV63821938; called by muse, mutect2, varscan2
- CD84 | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1366964952, COSV100246284; called by muse, mutect2
- CDC14A | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs749988305, COSV100324271; called by muse, mutect2, varscan2
- CDC25C | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100086927; called by muse, mutect2, varscan2
- CDC27 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs751273226, COSV99296244; called by muse, mutect2, varscan2
- CDCA7L | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs995765441, COSV100181017, COSV60954772; called by muse, mutect2, varscan2
- CDH1 | c.970G>T p.G324* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV55734605, COSV99932715; called by muse, mutect2, varscan2
- CDH10 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52575394; called by muse, mutect2, varscan2
- CDH23 | c.8032C>T p.R2678C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56476917; called by muse, mutect2, varscan2
- CDH23 | c.9523C>T p.R3175C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770796134, CM078756, COSV99823956; called by muse, mutect2, varscan2
- CEACAM20 | c.1520T>C p.L507P | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100387040; called by muse, mutect2, varscan2
- CECR2 | c.2035G>A p.G679R (on ENST00000342247 / NM_001290047.2; = p.G496R on NM_001290046.1) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs572732838, COSV99379180; called by muse, mutect2, varscan2
- CELSR2 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV54766438; called by muse, mutect2, varscan2
- CELSR2 | c.2335G>A p.V779M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as rs771837056, COSV99604795; called by muse, mutect2, varscan2
- CEP112 | c.2851T>C p.Y951H (on ENST00000392769 / NM_001353127.1; = p.Y207H on NM_001037325.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.04); catalogued as COSV100439510; called by muse, mutect2, varscan2
- CFAP43 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs758774398, COSV99530644; called by muse, mutect2, varscan2
- CFAP45 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141306445; called by muse, mutect2, varscan2
- CFAP47 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1444898459, COSV99935831; called by muse, mutect2, varscan2
- CFAP91 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs1423771462, COSV99847528; called by muse, mutect2, varscan2
- CHAC1 | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1280559612, COSV101471084; called by muse, mutect2, varscan2
- CHD2 | c.3748T>C p.C1250R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs111782863, COSV101246058; called by muse, mutect2, varscan2
- CHD3 | c.1920-2A>G p.X640_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100391740; called by muse, mutect2, varscan2
- CHD3 | c.3250C>T p.Q1084* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100391743; called by muse, mutect2, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- CHDH | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100179894; called by muse, mutect2, varscan2
- CHST6 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs569912782, COSV59999386; called by muse, mutect2, varscan2
- CHST7 | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99333146; called by muse, mutect2, varscan2
- CHURC1 | c.349T>G p.L117V (on ENST00000549115 / NM_001204063.1; = p.L118V on NM_145165.3) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV100767489; called by muse, mutect2, varscan2
- CIITA | c.2332G>A p.A778T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV100162623; called by muse, mutect2
- CIT | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.984); catalogued as COSV99951058; called by muse, mutect2, varscan2
- CIZ1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.226); catalogued as rs1178751637, COSV99477148; called by muse, mutect2, varscan2
- CKAP2 | c.1228A>C p.M410L (on ENST00000378037 / NM_001098525.2; = p.M409L on NM_018204.5) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV99318480; called by muse, mutect2, varscan2
- CKAP5 | c.3581A>G p.E1194G | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100371485; called by muse, mutect2, varscan2
- CKM | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1313579937, COSV99488903; called by muse, mutect2, varscan2
- CLCNKA | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs1483344638, COSV100510354; called by muse, mutect2, varscan2
- CLDND1 | c.-20C>T | Splice Region (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100360819; called by muse, mutect2, varscan2
- CLEC9A | c.470T>C p.M157T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100872879; called by muse, mutect2, varscan2
- CLIP1 | c.3857A>G p.K1286R (on ENST00000620786 / NM_001247997.1; = p.K1275R on NM_002956.2) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs113078373, COSV100212451; called by muse, mutect2, varscan2
- CLIP2 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99792357; called by muse, mutect2, varscan2
- CLK1 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs147917922, COSV100362478; called by muse, mutect2, varscan2
- CLMN | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54180818; called by muse, mutect2, varscan2
- CLSPN | c.3400C>T p.R1134* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV52049296; called by muse, mutect2, varscan2
- CNKSR1 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV100836725, COSV100836795; called by muse, mutect2, varscan2
- CNOT4 | c.230G>T p.R77M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV100212275; called by muse, mutect2, varscan2
- CNTD1 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs756525112, COSV59312169; called by muse, mutect2, varscan2
- COBLL1 | c.3472C>T p.R1158* (on ENST00000392717; = p.R1120* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as rs868427833, COSV52067513; called by muse, mutect2, varscan2
- COL14A1 | c.4897G>A p.A1633T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99920776; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 14/38 reads (37%) | catalogued as rs760493024; called by mutect2, varscan2
- COL5A3 | c.1216T>C p.S406P | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99319814; called by muse, mutect2, varscan2
- COL6A2 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs760263812, COSV100154339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.5345A>G p.D1782G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99801751; called by muse, mutect2, varscan2
- COLEC12 | c.1968del p.K656Nfs*4 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as COSV101232229; called by pindel, varscan2
- COP1 | c.621G>T p.L207F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.441); catalogued as COSV100443959; called by muse, mutect2, varscan2
- COPB1 | c.2101C>T p.Q701* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99999937; called by muse, mutect2, varscan2
- CORO7 | c.602C>A p.P201Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV99228160, COSV99228274; called by muse, mutect2
- COX17 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV99660458; called by muse, mutect2, varscan2
- CPQ | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55155730; called by muse, mutect2
- CPQ | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV99614990; called by muse, mutect2, varscan2
- CPSF7 | c.166C>T p.R56C (on ENST00000394888 / NM_001136040.4; = p.R99C on NM_024811.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs772924995, COSV61212974; called by muse, mutect2, varscan2
- CRB1 | c.652+2T>C p.X218_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100959504; called by muse, mutect2
- CRB2 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV100749750; called by muse, varscan2
- CRB2 | c.2408C>T p.A803V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs932396631, COSV63503099; called by muse, mutect2, varscan2
- CROCC | c.2126C>T p.A709V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs757160343, COSV100978423; called by muse, mutect2, varscan2
- CSAD | c.4G>A p.A2T (on ENST00000444623 / NM_001244705.2; = p.A29T on NM_015989.5) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as COSV99914705, COSV99915065; called by muse, mutect2, varscan2
- CSDE1 | c.632T>C p.F211S (on ENST00000358528 / NM_001007553.3; = p.F180S on NM_007158.6) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV54763025, COSV99796063; called by muse, mutect2, varscan2
- CSF2RA | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs758879393, COSV100817754; called by muse, mutect2, varscan2
- CSMD2 | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.487); catalogued as COSV99595746; called by muse, mutect2, varscan2
- CSPG4 | c.6245G>A p.R2082H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs778659779, COSV100413649; called by muse, mutect2, varscan2
- CTCF | c.1258G>T p.G420C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV99866643; called by muse, mutect2, varscan2
- CTLA4 | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99865469; called by muse, mutect2, varscan2
- CUL7 | c.4408A>T p.M1470L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99539279; called by muse, mutect2, varscan2
- CUX1 | c.1756G>A p.V586M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99473223; called by muse, mutect2, varscan2
- CXorf66 | c.502T>C p.S168P | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as COSV65168935; called by muse, mutect2
- CYLD | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100282776, COSV61094299; called by muse, mutect2, varscan2
- DBH | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs766166337, COSV55039535; called by muse, mutect2, varscan2
- DBNL | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as rs1187377992, COSV99803933; called by muse, mutect2, varscan2
- DCAF5 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as rs1379174992, COSV58462928; called by muse, mutect2, varscan2
- DCLK1 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1212119744, COSV99709232; called by muse, mutect2, varscan2
- DCST1 | c.1596G>A p.M532I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV99664613; called by muse, mutect2, varscan2
- DCST2 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1474128194, COSV55050905; called by muse, mutect2, varscan2
- DDX25 | c.1327C>A p.L443I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as COSV99700138; called by muse, mutect2, varscan2
- DDX39A | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as COSV99660532; called by muse, mutect2, varscan2
- DEFB127 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV101213900; called by muse, mutect2, varscan2
- DENND1A | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs554854472, COSV101011339; called by muse, mutect2
- DENND2C | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | catalogued as COSV101283975; called by muse, mutect2, varscan2
- DENND3 | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99371728; called by muse, mutect2, varscan2
- DGKA | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1404186075, COSV59388511; called by muse, mutect2, varscan2
- DHX30 | c.1534C>T p.R512C (on ENST00000445061 / NM_138615.3; = p.R473C on NM_014966.3) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1209005438, COSV99276386; called by muse, mutect2, varscan2
- DHX40 | c.1806G>T p.Q602H | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.87); catalogued as COSV99233264; called by muse, mutect2
- DHX57 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs369485938; called by muse, mutect2, varscan2
- DIDO1 | c.5905G>T p.D1969Y | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV99827237; called by muse, mutect2, varscan2
- DIDO1 | c.5653G>A p.A1885T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1281889786, COSV56631722; called by muse, mutect2, varscan2
- DIP2A | c.952A>G p.S318G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100596356; called by muse, mutect2
- DIPK2A | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100237467; called by muse, mutect2, varscan2
- DMRT2 | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52403719; called by muse, mutect2, varscan2
- DNAAF1 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs376164700; called by muse, mutect2, varscan2
- DNAH1 | c.11885C>T p.T3962M | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs759070063, COSV56230338, COSV56235904; called by muse, mutect2, varscan2
- DNAH17 | c.12029C>T p.T4010I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV101103547; called by muse, mutect2
- DNAH3 | c.3767C>T p.A1256V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV99770784; called by muse, mutect2, varscan2
- DNAH5 | c.12727C>T p.R4243C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs150357258; called by muse, mutect2, varscan2
- DNAI4 | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs375562160; called by muse, mutect2, varscan2
- DNAJC11 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.051); catalogued as rs199968865; called by mutect2, varscan2
- DNMBP | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs770587503, COSV100143811; called by muse, mutect2, varscan2
- DNMT1 | c.4613G>A p.R1538H | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100533098; called by muse, mutect2, varscan2
- DOCK1 | c.3356G>A p.R1119Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.083); catalogued as rs762364778, COSV54739562; called by muse, mutect2, varscan2
- DOCK2 | c.3616A>G p.N1206D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99915665; called by muse, mutect2, varscan2
- DOCK6 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.144); catalogued as rs376784362; called by muse, mutect2, varscan2
- DPH5 | c.392T>A p.V131D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100587497, COSV59858931; called by muse, mutect2, varscan2
- DPP9 | c.733G>A p.V245I (on ENST00000598800; = p.V274I on NM_139159.5) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.309); catalogued as rs769162859, COSV99506528; called by muse, mutect2, varscan2
- DPY19L1 | c.1202A>T p.E401V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV100205047; called by muse, mutect2, varscan2
- DROSHA | c.3005C>T p.A1002V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV100757830; called by muse, mutect2
- DRP2 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs766073418, COSV101235182; called by muse, mutect2, varscan2
- DST | c.15544G>T p.E5182* (on ENST00000361203 / NM_001374722.1; = p.E2770* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV55007022, COSV55018193; called by muse, mutect2, varscan2
- DST | c.10474G>A p.V3492M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs754875119, COSV99751778, COSV99758395; called by muse, mutect2
- DTX3 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1321210770, COSV99678325; called by muse, mutect2, varscan2
- DTX4 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV99915972; called by muse, mutect2
- DUSP10 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.145); catalogued as rs147900867; called by mutect2, varscan2
- DUSP14 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs751469260; called by muse, mutect2
- DYNC1LI2 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs777840298, COSV99263279; called by muse, mutect2, varscan2
- DYNC2H1 | c.7370A>G p.H2457R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV100519864; called by muse, mutect2, varscan2
- DYRK1B | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs966556487, COSV99695438; called by muse, mutect2, varscan2
- DYTN | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs183705947; called by muse, mutect2, varscan2
- E2F2 | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1418527136, COSV100674871; called by muse, mutect2, varscan2
- E2F3 | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as COSV100686314, COSV60895920; called by muse, mutect2, varscan2
- E2F7 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs780614837, COSV59739397; called by muse, mutect2, varscan2
- EBF1 | c.1588C>A p.L530I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.137); catalogued as COSV58171148; called by muse, mutect2, varscan2
- ECEL1 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs775694744, COSV58812940; called by muse, mutect2, varscan2
- ECPAS | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.139); catalogued as COSV99399368; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1234C>T p.R412C (on ENST00000361735 / NM_015935.5; = p.R326C on NM_014955.3) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274999532, COSV100675868; called by mutect2, varscan2
- EEF2 | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.976); catalogued as rs767823532, COSV58578765; called by muse, mutect2, varscan2
- EHD2 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs371409023; called by muse, mutect2, varscan2
- EIF2AK3 | c.1502T>C p.L501P | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.087); catalogued as rs564017955, COSV100304143; called by muse, mutect2, varscan2
- EIF3A | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV100974837; called by muse, mutect2, varscan2
- ELF2 | c.959T>C p.L320S (on ENST00000379550 / NM_001331036.2; = p.L260S on NM_006874.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.283); catalogued as COSV99643302; called by muse, varscan2
- ELOA2 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99798239; called by muse, mutect2, varscan2
- EML5 | c.5774C>T p.A1925V (on ENST00000380664; = p.A1933V on NM_183387.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as COSV99193275; called by muse, mutect2, varscan2
- ENAM | c.2857A>G p.R953G | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as rs762021258, COSV101253352; called by muse, mutect2
- ENOX1 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1011586241, COSV99817291; called by muse, mutect2, varscan2
- EPB41L1 | c.1452G>A p.P484= | Splice Region (SNP) | VAF 7/23 reads (30%) | catalogued as rs757050614, COSV99151722; called by muse, mutect2, varscan2
- EPG5 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV99958158; called by muse, mutect2, varscan2
- EPHA8 | c.1892A>G p.E631G | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99385773; called by muse, mutect2, varscan2
- EPHB1 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs533462328, COSV67662549; called by muse, mutect2, varscan2
- EPHB3 | c.1832C>A p.P611H | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382842; called by muse, mutect2
- ERAL1 | c.901C>A p.H301N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV99650502; called by muse, mutect2, varscan2
- ESYT1 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99920343; called by muse, mutect2, varscan2
- EVA1A | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV52057174; called by muse, mutect2, varscan2
- EXD3 | c.1982A>G p.H661R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV100573978; called by muse, varscan2
- EXOSC10 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as rs754230703, COSV100442944; called by muse, mutect2, varscan2
- EZH2 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs765147666, COSV57450464; called by muse, mutect2, varscan2
- FAM189A2 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs149212614; called by muse, mutect2, varscan2
- FAM20B | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs768868593, COSV55380356, COSV99762090; called by muse, mutect2, varscan2
- FAM222B | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs752194762, COSV100368745; called by muse, varscan2
- FANCM | c.2975G>A p.R992K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99951702; called by muse, mutect2, varscan2
- FARP2 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959300237, COSV99885627; called by mutect2, varscan2
- FAT1 | c.3947C>T p.A1316V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as COSV101499659; called by muse, mutect2, varscan2
- FAT2 | c.12211C>T p.R4071C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); catalogued as rs768392091, COSV55824158; called by muse, mutect2, varscan2
- FAT4 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101272876; called by muse, mutect2, varscan2
- FAT4 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV101272877; called by muse, mutect2, varscan2
- FBF1 | c.578G>T p.G193V (on ENST00000586717; = p.G207V on NM_001319193.1) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100045623; called by muse, mutect2, varscan2
- FBLN1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17852050, COSV99411550; called by muse, mutect2, varscan2
- FBN1 | c.4397G>A p.G1466D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100356473; called by muse, mutect2, varscan2
- FBXL7 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100310969; called by muse, mutect2, varscan2
- FBXO24 | c.962del p.G321Efs*69 (on ENST00000241071 / NM_033506.3; = p.G359Efs*69 on NM_012172.5) | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs1412286983; called by mutect2, pindel, varscan2
- FBXO3 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs77122959, COSV55765257; called by muse, mutect2, varscan2
- FBXW10 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100111785; called by muse, mutect2, varscan2
- FCRL5 | c.1537C>A p.P513T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV100709349; called by muse, mutect2, varscan2
- FCSK | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377513686, COSV99851312; called by muse, mutect2, varscan2
- FEZ1 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99631226; called by muse, mutect2, varscan2
- FGD6 | c.3302G>A p.R1101Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1416061781, COSV59690240; called by muse, mutect2, varscan2
- FGF23 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs200445443, COSV52975670; called by muse, mutect2, varscan2
- FGFR4 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.095); catalogued as COSV99450987; called by muse, mutect2, varscan2
- FGFR4 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99450991; called by muse, mutect2, varscan2
- FHL2 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs371759004; called by muse, mutect2, varscan2
- FHL5 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs780594540, COSV58735060; called by muse, mutect2, varscan2
- FICD | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as rs987255028, COSV99934468; called by muse, mutect2, varscan2
- FILIP1L | c.2345G>T p.R782M (on ENST00000354552 / NM_182909.3; = p.R542M on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100496607; called by muse, mutect2, varscan2
- FLNA | c.3815G>A p.R1272H | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV61038356; called by muse, mutect2, varscan2
- FLRT2 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs149005998; called by muse, mutect2, varscan2
- FLT1 | c.125T>A p.I42N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV99167423; called by muse, mutect2, varscan2
- FMN1 | c.3331G>A p.E1111K (on ENST00000616417 / NM_001277313.2; = p.E888K on NM_001103184.4) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.134); catalogued as rs754156512, COSV100569329; called by muse, mutect2, varscan2
- FMNL1 | c.2578C>T p.R860W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100056984; called by muse, mutect2, varscan2
- FN1 | c.6673T>C p.S2225P (on ENST00000359671 / NM_001365524.2; = p.S2194P on NM_002026.4) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as COSV100118366; called by muse, mutect2, varscan2
- FOXD4L1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1419402874, COSV99380840; called by muse, mutect2, varscan2
- FOXJ2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.23); catalogued as rs769288818, COSV99369005; called by muse, mutect2, varscan2
- FOXK1 | c.1967C>A p.S656Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100195883, COSV61067278; called by muse, mutect2, varscan2
- FOXN2 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100489512; called by muse, mutect2, varscan2
- FOXO4 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100447062; called by muse, mutect2, varscan2
- FPGS | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768545932, COSV100948802, COSV100948912; called by muse, mutect2, varscan2
- FREM1 | c.3581G>A p.G1194D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747106501, COSV66524661; called by muse, mutect2, varscan2
- FTSJ3 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1245439560, COSV59561717; called by muse, mutect2, varscan2
- FTSJ3 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as COSV100037465; called by muse, mutect2, varscan2
- FYB1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as COSV100686463; called by muse, mutect2, varscan2
- FZD2 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV59528430; called by muse, mutect2, varscan2
- FZD6 | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); catalogued as rs201432167, COSV62470682; called by muse, mutect2, varscan2
- FZR1 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs201109329, COSV100553888; called by muse, mutect2, varscan2
- GABPA | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs957953541, COSV61396369; called by muse, mutect2, varscan2
- GABRB1 | c.78C>T p.H26= | Splice Region (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99783620; called by muse, mutect2, varscan2
- GABRG2 | c.226G>T p.G76* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100729873; called by muse, mutect2, varscan2
- GALNT2 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764812990, COSV100795916; called by mutect2, varscan2
- GALNTL6 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs776721936, COSV72491103; called by muse, mutect2, varscan2
- GCOM1 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs756208577, COSV51088533; called by muse, mutect2, varscan2
- GDPD4 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs549224703, COSV60016851; called by mutect2, varscan2
- GEMIN7 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV54319212; called by muse, mutect2, varscan2
- GET3 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99662298; called by muse, mutect2
- GIN1 | c.739A>G p.K247E | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV101204422; called by muse, mutect2, varscan2
- GJA3 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV99576527; called by muse, mutect2, varscan2
- GK | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1384912336, COSV100971006; called by muse, mutect2, varscan2
- GLRA2 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99491647; called by muse, mutect2, varscan2
- GMPPA | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58006617, COSV58006649; called by muse, mutect2, varscan2
- GPATCH2L | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99833947; called by muse, mutect2, varscan2
- GPATCH8 | c.2738A>T p.D913V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.829); catalogued as rs1239637709, COSV100132885; called by muse, mutect2, varscan2
- GPD1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1128867, COSV99993854; called by muse, mutect2, varscan2
- GPHN | c.1057C>T p.R353* (on ENST00000315266 / NM_001377519.1; = p.R386* on NM_020806.5) | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV59471996; called by muse, mutect2, varscan2
- GPR137 | c.1254G>T p.*418Yext*? | Nonstop Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100464538; called by muse, mutect2, varscan2
- GPR31 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.061); catalogued as rs200346870, COSV100834129; called by muse, mutect2, varscan2
- GPR6 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as rs757587850, COSV51571602; called by muse, mutect2, varscan2
- GPS1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs199969665, COSV100136150; called by muse, mutect2, varscan2
- GREB1 | c.5090G>A p.R1697Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.04); catalogued as rs1235407879, COSV52198746; called by muse, mutect2, varscan2
- GRIK2 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.76); catalogued as rs766548594, COSV100029616; called by mutect2, varscan2
- GRIN2A | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100410744; called by muse, mutect2, varscan2
- GRIN2B | c.4255C>T p.P1419S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101663199; called by muse, mutect2, varscan2
- GRIPAP1 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.942); catalogued as COSV100904384; called by muse, mutect2, varscan2
- GRM7 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs1390058794, COSV63143649, COSV63161230; called by muse, mutect2, varscan2
- GRTP1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.179); catalogued as rs1221641661, COSV100391412; called by muse, mutect2, varscan2
- GSK3A | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs774878085, COSV55898364; called by muse, mutect2, varscan2
- GTF3C1 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100649232; called by muse, varscan2
- GUCY1A2 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); catalogued as COSV99977071; called by muse, mutect2, varscan2
- GUSB | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.172); catalogued as rs538431094, COSV100512779; called by muse, mutect2, varscan2
- GXYLT1 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as rs199982685, COSV55137366; called by muse, mutect2, varscan2
- H6PD | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs1329379803, COSV66230884; called by muse, mutect2, varscan2
- HAS1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as COSV55789980; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as COSV100625709; called by mutect2, varscan2
- HEATR5B | c.3074G>A p.R1025H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757387757, COSV51849056; called by muse, mutect2, varscan2
- HECA | c.986T>C p.L329S | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.848); catalogued as COSV100866262; called by muse, mutect2
- HGFAC | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.112); catalogued as rs534595424, COSV100123381; called by muse, mutect2, varscan2
- HIC2 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV68042054; called by muse, mutect2, varscan2
- HIRA | c.1164G>T p.E388D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV54276735, COSV99600924; called by muse, mutect2, varscan2
- HNRNPAB | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.246); catalogued as rs146516910; called by muse, mutect2, varscan2
- HOXC12 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.227); catalogued as COSV99678820; called by muse, mutect2, varscan2
- HPD | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100000237, COSV56641249; called by muse, mutect2, varscan2
- HRNR | c.3353A>G p.Q1118R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100913980; called by mutect2, varscan2
- HS3ST1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50022953; called by muse, mutect2, varscan2
- HSPA14 | c.734G>T p.R245I | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101000702; called by muse, mutect2
- HSPB7 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.067); catalogued as rs1192545737, COSV58890680; called by muse, mutect2, varscan2
- HSPB9 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV99863718; called by muse, mutect2, varscan2
- HSPG2 | c.12116C>T p.S4039L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1378916104, COSV100760951; called by muse, mutect2, varscan2
- HTR1A | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1427412024, COSV60500218; called by muse, mutect2, varscan2
- HTR1B | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.575); catalogued as COSV100885502; called by muse, mutect2, varscan2
- HTR3A | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs34111946; called by muse, mutect2, varscan2
- HUWE1 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.727); catalogued as rs1247481031, COSV53368823, COSV99474345; called by muse, mutect2, varscan2
- HYAL4 | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV99772491; called by muse, mutect2, varscan2
- HYOU1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs781981889, COSV101345681; called by muse, mutect2, varscan2
- ICA1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.017); catalogued as rs1326826607, COSV99655953; called by muse, mutect2, varscan2
- ICAM4 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV53425039; called by muse, mutect2, varscan2
- IGF2R | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762519931, COSV63627359; called by muse, mutect2, varscan2
- IGKV2D-29 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV101534399; called by muse, mutect2
- IGSF9 | c.2308C>T p.R770C (on ENST00000368094 / NM_001135050.2; = p.R754C on NM_020789.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1327919185, COSV63639080; called by muse, mutect2, varscan2
- IGSF9 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63641307; called by muse, mutect2, varscan2
- IGSF9B | c.2026C>A p.L676M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100318481, COSV58068488, COSV58072530; called by muse, mutect2, varscan2
- IL11 | c.182G>T p.R61M | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99215151; called by muse, mutect2
- IL12RB2 | c.2555A>G p.Q852R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99255682; called by muse, mutect2, varscan2
- IL15 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56726682; called by muse, mutect2, varscan2
- IL1A | c.358A>C p.S120R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99641524; called by muse, mutect2, varscan2
- IL2RG | c.1031A>G p.E344G | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.63); catalogued as COSV99340426; called by mutect2, varscan2
- INHBA | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs761497837, COSV54222443; called by muse, mutect2, varscan2
- INSRR | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100948131; called by muse, mutect2, varscan2
- INTS1 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV101248358, COSV99072201; called by muse, mutect2, varscan2
- INTS10 | c.836+1G>A p.X279_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV101208726, COSV101208748; called by muse, mutect2, varscan2
- INTS7 | c.2819G>A p.R940H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as rs969098937, COSV65344388; called by muse, mutect2, varscan2
- IPO9 | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100843576; called by muse, mutect2, varscan2
- IQCA1 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs763204451, COSV54507339; called by muse, mutect2, varscan2
- IQSEC1 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs777017219, COSV99832409; called by muse, mutect2, varscan2
- IRAK1 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs782281305, COSV64113467; called by muse, mutect2, varscan2
- IRAK2 | c.1559G>A p.G520D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV99844368; called by muse, mutect2
- IRF2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs541749119, COSV66929956, COSV66930732; called by muse, mutect2, varscan2
- IRX2 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as rs1199176093, COSV100121933; called by muse, mutect2, varscan2
- ITGA5 | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV53220675; called by mutect2, varscan2
- ITGAE | c.3040C>T p.R1014* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as rs1567515189, COSV99561580; called by muse, mutect2, varscan2
- ITGB2 | c.1870G>A p.V624I (on ENST00000302347; = p.V600I on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs759846070, COSV56610880, COSV56614686; called by muse, mutect2, varscan2
- ITGB2 | c.593G>A p.C198Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100186147; called by muse, mutect2, varscan2
- ITGB4 | c.5014G>A p.V1672I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs755748059, COSV99564829; called by mutect2, varscan2
- ITGB4 | c.5054-1G>T p.X1685_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99564836; called by mutect2, varscan2
- ITPKB | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs751539212, COSV55257112; called by muse, mutect2
- ITSN1 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751006736, COSV66080668; called by muse, mutect2, varscan2
- JAG2 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100078847; called by muse, mutect2, varscan2
- JRKL | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as COSV53592225; called by muse, mutect2, varscan2
- KALRN | c.5113G>A p.A1705T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs540920510, COSV62564300; called by muse, mutect2, varscan2
- KBTBD12 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs1216330782, COSV100675537; called by muse, mutect2, varscan2
- KBTBD8 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs944350795, COSV55126891; called by muse, mutect2, varscan2
- KCNG4 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369643936, COSV57584780; called by muse, mutect2, varscan2
- KCNH4 | c.1571G>A p.S524N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1453187607, COSV99237957; called by muse, mutect2, varscan2
- KCNH4 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52921554; called by muse, mutect2, varscan2
- KCNJ3 | c.796T>C p.S266P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV54531542; called by muse, mutect2, varscan2
- KCNK13 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs547806943, COSV56417066; called by muse, mutect2, varscan2
- KCNS2 | c.1098G>A p.W366* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99751482; called by muse, mutect2
- KCTD8 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs143160739, COSV100759683, COSV63585505, COSV63589266; called by muse, mutect2, varscan2
- KDM2A | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100445837; called by muse, mutect2, varscan2
- KDM3B | c.4627G>A p.A1543T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100070266; called by muse, mutect2, varscan2
- KDM4A | c.622T>C p.W208R | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969669; called by muse, mutect2, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs771545848; called by mutect2, varscan2
- KDM5C | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100949498; called by muse, mutect2, varscan2
- KIAA0513 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV99261346; called by muse, mutect2, varscan2
- KIAA1109 | c.8152G>A p.D2718N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs769159528, COSV52663152; called by muse, mutect2, varscan2
- KIDINS220 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as rs1034611870, COSV99876517; called by muse, mutect2, varscan2
- KIF23 | c.2857G>A p.A953T (on ENST00000260363; = p.A849T on NM_004856.7) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.355); catalogued as rs1281499873, COSV52980071, COSV99532701; called by muse, mutect2, varscan2
- KIF26B | c.4634G>A p.S1545N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100833484; called by muse, mutect2, varscan2
- KIF5C | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101276215; called by muse, mutect2, varscan2
- KIF9 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.305); catalogued as rs1407738082, COSV55524000; called by muse, mutect2, varscan2
- KLHL18 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231322; called by muse, mutect2, varscan2
- KLHL24 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs750740624, COSV99665193; called by muse, mutect2, varscan2
- KLHL40 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99825797; called by muse, mutect2, varscan2
- KMT2A | c.8118G>T p.E2706D | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); catalogued as COSV100629961; called by muse, mutect2, varscan2
- KMT2D | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs780096090, COSV99986024; called by muse, mutect2, varscan2
- KNG1 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99405882; called by muse, mutect2, varscan2
- KRIT1 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100388954; called by muse, mutect2, varscan2
- KRT33B | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs371896942, COSV99290482; called by muse, mutect2, varscan2
- KRT6A | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as rs561751156, COSV100417254; called by muse, mutect2, varscan2
- KRTAP13-2 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1285023388, COSV101299676; called by muse, mutect2, varscan2
- KRTAP5-1 | c.233dup p.C79Lfs*149 | Frame Shift Ins (INS) | VAF 18/53 reads (34%) | catalogued as rs1055060334; called by mutect2, pindel, varscan2
- KSR2 | c.2122A>G p.K708E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100196791; called by muse, mutect2, varscan2
- L3MBTL2 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778523048, COSV99346180; called by muse, mutect2, varscan2
- LAMA3 | c.3563C>T p.A1188V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.168); catalogued as COSV100557695; called by muse, mutect2
- LAMC3 | c.2497C>T p.R833C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375538194; called by muse, mutect2, varscan2
- LAMP2 | c.1042T>G p.F348V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99568917; called by muse, mutect2, varscan2
- LANCL2 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99634794; called by muse, mutect2, varscan2
- LARP4 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1463498908, COSV99529711; called by muse, mutect2, varscan2
- LARP4B | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); catalogued as rs1351264433, COSV100295713; called by muse, mutect2, varscan2
- LATS2 | c.1871G>T p.R624M | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV101231678; called by muse, mutect2, varscan2
- LCE1A | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs749443782, COSV100632109; called by muse, mutect2, varscan2
- LCE1F | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1199594549, COSV57669177; called by muse, varscan2
- LCE5A | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV100524171; called by muse, mutect2, varscan2
- LCOR | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53714647, COSV53717203; called by muse, mutect2, varscan2
- LHFPL1 | c.611T>C p.M204T | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1414328508, COSV100914528; called by muse, mutect2, varscan2
- LHX8 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.989); catalogued as COSV99634469; called by muse, mutect2, varscan2
- LPA | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.219); catalogued as rs765765045, COSV60298647; called by muse, mutect2, varscan2
- LPO | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764112101, COSV99229441; called by muse, mutect2, varscan2
- LRCH2 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1556544107, COSV100407614; called by muse, mutect2, varscan2
- LRFN5 | c.1943G>A p.G648D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.051); catalogued as COSV99985567; called by muse, mutect2, varscan2
- LRP10 | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100612520; called by muse, mutect2, varscan2
- LRP1B | c.11916G>T p.R3972S | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV101261453; called by muse, mutect2, varscan2
- LRP1B | c.9369A>G p.I3123M | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs749878733, COSV101261455; called by muse, mutect2, varscan2
- LRRC37A2 | c.4348G>A p.V1450M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs758776686, COSV100238864; called by muse, mutect2, varscan2
- LRRC43 | c.1667G>A p.R556Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs754963252, COSV100148861; called by muse, mutect2, varscan2
- LRRN1 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1362820506, COSV100076619; called by muse, mutect2, varscan2
- LRRTM1 | c.1058T>C p.V353A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as rs1290036260, COSV99703254; called by muse, mutect2, varscan2
- LSAMP | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100372919; called by muse, mutect2, varscan2
- LTBP2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.059); catalogued as rs754478146, COSV56207737; called by muse, mutect2, varscan2
- LYNX1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.175); catalogued as COSV100235845; called by muse, mutect2, varscan2
- LZTR1 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763127267, COSV53146118; called by muse, mutect2, varscan2
- MAB21L1 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59777576; called by muse, mutect2, varscan2
- MACF1 | c.5054T>C p.L1685P | Missense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99247041; called by muse, mutect2, varscan2
- MACF1 | c.6335G>T p.R2112M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV99247043; called by muse, mutect2, varscan2
- MACF1 | c.6521C>T p.T2174I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as rs1452596057, COSV99247045; called by muse, mutect2, varscan2
- MACROD2 | c.336T>A p.C112* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99444119; called by muse, mutect2, varscan2
- MAEA | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs773721944, COSV99295728; called by muse, mutect2, varscan2
- MAEA | c.1118A>G p.D373G (on ENST00000303400 / NM_001017405.3; = p.D332G on NM_005882.5) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as COSV99295730; called by muse, mutect2, varscan2
- MAG | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1304260702, COSV62700378; called by muse, mutect2
- MAGEA11 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as COSV100290580; called by muse, mutect2, varscan2
- MAGEB3 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as rs149480290, COSV100854824, COSV64397409; called by muse, mutect2, varscan2
- MAGEC1 | c.2147A>T p.E716V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.062); catalogued as COSV99596630; called by muse, mutect2, varscan2
- MAGEC3 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as COSV100026153; called by muse, mutect2, varscan2
- MAGED2 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.534); catalogued as COSV99514783; called by muse, mutect2, varscan2
- MAGEL2 | c.3716C>T p.A1239V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as COSV100046243; called by muse, mutect2, varscan2
- MAGI1 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1481145301, COSV100443200, COSV58317356; called by muse, varscan2
- MAML3 | c.3410A>G p.N1137S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.97); catalogued as COSV101558536; called by muse, mutect2
- MAP1B | c.5440T>C p.C1814R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99702970; called by muse, mutect2, varscan2
- MAP1B | c.6230G>A p.R2077H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as rs34160030; called by muse, mutect2, varscan2
- MAP3K13 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs746379057, COSV53990910; called by muse, mutect2, varscan2
- MAP3K14 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as rs766888695, COSV100766570; called by mutect2, varscan2
- MAPK8IP3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs183206340, COSV99169792; called by muse, mutect2, varscan2
- MARCHF10 | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs758145509, COSV100248641; called by muse, mutect2, varscan2
- MARCHF3 | c.395G>T p.W132L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100428177, COSV58041518; called by muse, mutect2, varscan2
- MAST3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99446357; called by muse, mutect2, varscan2
- MATN2 | c.2783C>T p.A928V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.913); catalogued as COSV99647201; called by muse, mutect2, varscan2
- MATN4 | c.1603G>A p.E535K (on ENST00000372754; = p.E494K on NM_003833.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | PolyPhen benign (0.045); catalogued as COSV61351627; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs746267361; called by mutect2, varscan2
- MC1R | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.143); catalogued as COSV100206101; called by muse, mutect2, varscan2
- MDN1 | c.9658C>T p.R3220C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); catalogued as rs780718510, COSV101021250; called by muse, mutect2, varscan2
- MED12 | c.2636T>G p.L879R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100380086, COSV99048897; called by muse, mutect2, varscan2
- MED12 | c.3743A>T p.E1248V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV100380087; called by muse, mutect2, varscan2
- MED13 | c.4667C>T p.P1556L | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs771231439, COSV67262871; called by muse, mutect2, varscan2
- MED17 | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as rs1479963505, COSV99316267; called by muse, mutect2, varscan2
- MEGF11 | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs267604294, COSV99989282; called by muse, mutect2, varscan2
- MEPCE | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); catalogued as COSV99440258; called by muse, mutect2, varscan2
- MET | c.2189A>T p.N730I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV100577428; called by muse, varscan2
- MET | c.2252A>T p.K751I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100577430; called by muse, varscan2
- MICAL2 | c.1581G>T p.Q527H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99818428; called by muse, mutect2
- MIP | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778327521, CM153799, COSV57509364; called by muse, mutect2, varscan2
- MKI67 | c.4720C>T p.R1574W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs764163792, COSV64075278; called by muse, mutect2, varscan2
- MLEC | c.260C>A p.P87Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.094); catalogued as COSV99949765; called by muse, mutect2, varscan2
- MLXIP | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473149382, COSV59836777; called by muse, mutect2
- MON2 | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV99743665; called by muse, mutect2, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs757379917; called by mutect2, varscan2
- MOSPD2 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs748763207, COSV100996943; called by muse, mutect2, varscan2
- MPDZ | c.4805G>A p.R1602Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs372204991; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2933C>A p.P978Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100187251; called by muse, mutect2, varscan2
- MPP6 | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56035903; called by muse, mutect2, varscan2
- MROH7 | c.3414G>A p.M1138I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100274095; called by muse, mutect2, varscan2
- MRPL16 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774234238, COSV55701052; called by muse, mutect2, varscan2
- MRPL37 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771926988, COSV100289462; called by muse, mutect2, varscan2
- MRPL38 | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.861); catalogued as COSV99485608; called by muse, mutect2, varscan2
- MS4A3 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.309); catalogued as COSV99615026; called by muse, mutect2, varscan2
- MSH6 | c.3725G>A p.R1242H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750119, CD103561, CD143597, CM1411645, COSV52278636; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MSL1 | c.1799T>C p.L600S (on ENST00000398532 / NM_001365919.1; = p.L337S on NM_001012241.2) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as rs886489873, COSV100278224; called by muse, mutect2, varscan2
- MTFR2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151177675; called by muse, mutect2, varscan2
- MTMR10 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.926); catalogued as rs758142405, COSV100076382; called by muse, mutect2, varscan2
- MTMR3 | c.3385G>A p.D1129N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.95); catalogued as rs769082580, COSV100071405; called by muse, mutect2, varscan2
- MTNR1B | c.962G>T p.R321M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV99925373; called by muse, mutect2
- MTREX | c.2475dup p.A826Sfs*8 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | catalogued as rs760862419, COSV57930742; called by mutect2, varscan2
- MTRR | c.1912A>G p.R638G (on ENST00000264668; = p.R611G on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99242128; called by muse, mutect2
- MTSS2 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1485305599, COSV99852022; called by muse, mutect2, varscan2
- MUC15 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as COSV99846702; called by muse, mutect2, varscan2
- MUS81 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs765092249, COSV100337403; called by muse, mutect2, varscan2
- MX2 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1187092680, COSV100416202; called by muse, mutect2, varscan2
- MYBBP1A | c.2776G>A p.A926T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs200976848; called by muse, varscan2
- MYH10 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1172401222, COSV99346426; called by muse, mutect2, varscan2
- MYH13 | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs199750347; called by muse, mutect2, varscan2
- MYH3 | c.2600C>T p.S867L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs777604042, COSV99878964; called by muse, mutect2, varscan2
- MYH4 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777774759, COSV55126989, COSV99702332; called by muse, mutect2, varscan2
- MYH8 | c.1208G>A p.C403Y | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101238855; called by muse, mutect2
- MYL9 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99641188; called by muse, mutect2, varscan2
- MYO16 | c.876A>G p.S292= | Splice Region (SNP) | VAF 10/47 reads (21%) | catalogued as COSV51793297; called by muse, mutect2, varscan2
- MYO5C | c.3827A>G p.E1276G | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99955547; called by muse, mutect2, varscan2
- MYO7A | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs41298143, COSV68685688; called by muse, mutect2, varscan2
- MYOM1 | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.222); catalogued as COSV99868520; called by muse, mutect2, varscan2
- MYORG | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99898858; called by muse, mutect2
- MYT1 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746331377, COSV100115524; called by muse, mutect2, varscan2
- NALCN | c.4151G>A p.R1384Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51918056; called by muse, mutect2, varscan2
- NBEAL2 | c.2488G>A p.A830T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs751700790, COSV99437715; called by muse, mutect2, varscan2
- NCAM1 | c.486dup p.D163Rfs*22 | Frame Shift Ins (INS) | VAF 15/57 reads (26%) | catalogued as rs1555112729; called by mutect2, pindel, varscan2
- NCBP1 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1480959894, COSV100910660; called by muse, mutect2, varscan2
- NCF1 | c.511T>C p.S171P | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV99194330; called by muse, mutect2
- NCK2 | c.946T>C p.S316P | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99257077; called by muse, mutect2, varscan2
- NCLN | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs374589922; called by muse, mutect2
- NDST4 | c.1331A>G p.Q444R | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99997978; called by muse, mutect2
- NDUFA4L2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as rs1458104859, COSV100197419; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs747914168; called by mutect2, varscan2
- NECTIN2 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs1217007165, COSV99375285; called by muse, mutect2, varscan2
- NELFE | c.401A>G p.E134G | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV100952869; called by muse, mutect2, varscan2
- NFE2L3 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540554491, COSV50230958; called by muse, mutect2, varscan2
- NFIL3 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.154); catalogued as COSV99907055; called by muse, mutect2, varscan2
- NHS | c.4286+2T>C p.X1429_splice | Splice Site (SNP) | VAF 18/59 reads (31%) | catalogued as COSV101197010; called by muse, mutect2, varscan2
- NISCH | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs111273639; called by muse, mutect2, varscan2
- NKX2-2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV101010633; called by muse, mutect2, varscan2
- NMNAT2 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs201746612, COSV54268495; called by muse, mutect2, varscan2
- NOBOX | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199740315, COSV56194007; called by muse, mutect2, varscan2
- NOBOX | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV56194618; called by muse, mutect2, varscan2
- NOD2 | c.2572G>A p.G858S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.222); catalogued as rs760938311, COSV56053693; called by muse, mutect2, varscan2
- NOL4 | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99308547; called by muse, mutect2, varscan2
- NOS3 | c.583-2A>G p.X195_splice | Splice Site (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99872206; called by muse, mutect2, varscan2
- NOTCH2 | c.2135C>G p.P712R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV99866898; called by muse, mutect2, varscan2
- NOX1 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs766831994, COSV54194981; called by muse, mutect2, varscan2
- NR6A1 | c.274C>T p.R92W (on ENST00000487099 / NM_033334.4; = p.R88W on NM_001489.5) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100748716; called by muse, mutect2, varscan2
- NRIP1 | c.1652T>C p.V551A | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100013139; called by muse, mutect2, varscan2
- NRK | c.2429G>A p.R810Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs962537829, COSV54599369; called by muse, mutect2, varscan2
- NRP2 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753855535, COSV99785795; called by muse, mutect2, varscan2
- NRSN2 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs761781812, COSV66526723; called by muse, mutect2, varscan2
- NRXN2 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1428772338, COSV55458010; called by muse, mutect2
- NSMCE2 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.782); catalogued as rs776469721, COSV99787478; called by muse, mutect2, varscan2
- NUMA1 | c.4414G>A p.A1472T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as COSV100706654; called by muse, mutect2, varscan2
- NUP153 | c.4015C>A p.P1339T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100020861; called by muse, mutect2, varscan2
- NUP153 | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100020864; called by muse, mutect2, varscan2
- NUP210L | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs967513328, COSV99669179; called by muse, mutect2, varscan2
- NUP58 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101098928; called by muse, mutect2
- OAS1 | c.655T>C p.C219R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251530149, COSV99177295; called by muse, mutect2, varscan2
- OBSCN | c.9758G>A p.R3253Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs759315645, COSV52794713; called by muse, mutect2, varscan2
- OBSL1 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777770619, COSV99216596, COSV99217398; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as CD000269; called by mutect2, pindel, varscan2
- OGFRL1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV100965805; called by mutect2, varscan2
- OPLAH | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); catalogued as rs781965027, COSV70678846; called by muse, mutect2, varscan2
- OR10A3 | c.731A>G p.H244R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100660333; called by muse, mutect2, varscan2
- OR10H1 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV100612509; called by muse, mutect2, varscan2
- OR10J3 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs191809035, COSV100171900; called by muse, mutect2, varscan2
- OR10W1 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs532572497, COSV101223797; called by muse, mutect2, varscan2
- OR14I1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.363); catalogued as COSV100700545; called by muse, mutect2, varscan2
- OR2T33 | c.11G>T p.R4I | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV100532324; called by muse, mutect2, varscan2
- OR4X1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.894); catalogued as rs61915300; called by muse, mutect2, varscan2
- OR4X2 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1165881517, COSV100183352; called by muse, mutect2, varscan2
- OR51V1 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100343529; called by muse, mutect2, varscan2
- OR52E8 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs777735568, COSV101191101; called by muse, mutect2, varscan2
- OR52N5 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs372227128; called by muse, mutect2, varscan2
- OR8K5 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.424); catalogued as COSV100537344; called by muse, mutect2, varscan2
- ORMDL3 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100401590; called by muse, mutect2, varscan2
- PACS1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV100270618; called by muse, mutect2, varscan2
- PACS1 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs757068332, COSV100270623; called by muse, mutect2, varscan2
- PADI4 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as rs763921861, COSV64923101; called by muse, mutect2, varscan2
- PAK1IP1 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs751776397, COSV65435973; called by muse, mutect2, varscan2
- PAN2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99228523; called by muse, mutect2, varscan2
- PAPLN | c.3178C>T p.R1060W (on ENST00000554301; = p.R1033W on NM_173462.4) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as rs772777973, COSV99390496; called by muse, mutect2, varscan2
- PAPOLA | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV53479338; called by muse, mutect2, varscan2
- PARP10 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as COSV100478365; called by muse, mutect2, varscan2
- PAX7 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs774609612, COSV64749043; called by muse, mutect2, varscan2
- PAX7 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs769536224, COSV100946625; called by mutect2, varscan2
- PC | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs752021062, COSV100852353; called by muse, mutect2, varscan2
- PCDH15 | c.4027C>T p.P1343S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV100228037; called by muse, mutect2, varscan2
- PCDH18 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100787530; called by muse, mutect2
- PCDH18 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100787531; called by muse, mutect2, varscan2
- PCDHA13 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1345534362, COSV99169862; called by muse, varscan2
- PCDHA13 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as rs1554181508, COSV56543717; called by muse, varscan2
- PCDHA13 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); catalogued as rs782467193, COSV56496419, COSV56539642; called by muse, mutect2, varscan2
- PCDHA2 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV65367699, COSV65369574; called by muse, mutect2, varscan2
- PCDHA4 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs782714901, COSV63541037; called by muse, mutect2, varscan2
- PCDHB1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376346263; called by mutect2, varscan2
- PCDHB10 | c.2338G>A p.G780S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as COSV99505070; called by muse, mutect2, varscan2
- PCDHB16 | c.2077G>A p.A693T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV53372785; called by muse, mutect2, varscan2
- PCDHB2 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.458); catalogued as rs1554271488, COSV50567725; called by muse, mutect2, varscan2
- PCDHB4 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.798); catalogued as rs782814150, COSV52019478, COSV52024742; called by muse, mutect2, varscan2
- PCDHB8 | c.2028G>T p.E676D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); catalogued as COSV99177448; called by muse, mutect2, varscan2
- PCDHGC5 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1224625072, COSV52771582; called by muse, mutect2, varscan2
- PCLO | c.5247dup p.G1750Rfs*22 | Frame Shift Ins (INS) | VAF 11/63 reads (17%) | catalogued as rs761208405; called by mutect2, pindel, varscan2
- PCNT | c.7662C>G p.S2554R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1309729750, COSV100856065; called by muse, mutect2, varscan2
- PCYOX1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52475530; called by muse, mutect2, varscan2
- PDE3A | c.1522A>G p.K508E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV62969327; called by muse, mutect2, varscan2
- PDE3B | c.2678C>T p.T893M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201854538, COSV56386989; called by muse, mutect2, varscan2
- PDE5A | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.581); catalogued as rs200971951; called by muse, mutect2, varscan2
- PDZD8 | c.3277C>A p.H1093N | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100042093; called by muse, mutect2, varscan2
- PER1 | c.3287A>C p.K1096T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100424869; called by mutect2, varscan2
- PER2 | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99612617; called by muse, mutect2, varscan2
- PFKM | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs766431669, COSV56658123; called by muse, mutect2, varscan2
- PGBD2 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as rs760946071, COSV61401091; called by muse, mutect2, varscan2
- PHC2 | c.2548G>A p.A850T (on ENST00000257118 / NM_198040.2; = p.A315T on NM_004427.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472472276, COSV99930630; called by muse, mutect2, varscan2
- PHC2 | c.2095C>T p.R699W (on ENST00000257118 / NM_198040.2; = p.R164W on NM_004427.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773965245, COSV57101546; called by muse, mutect2, varscan2
- PHEX | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs376291775, COSV65074605; called by muse, varscan2
- PHKA2 | c.1223T>C p.I408T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs1428613360, COSV66053408; called by muse, mutect2, varscan2
- PHLDB1 | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100616811; called by muse, mutect2, varscan2
- PHLPP1 | c.4174G>A p.V1392M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs772092116, COSV99409302; called by muse, mutect2, varscan2
- PHOX2B | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.019); catalogued as rs779913205, COSV99891728; called by muse, mutect2, varscan2
- PI4KA | c.4201C>T p.R1401C | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1283694869, COSV99748700; called by muse, mutect2, varscan2
- PID1 | c.541G>A p.A181T (on ENST00000354069 / NM_001330156.1; = p.A179T on NM_017933.5) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs780979505, COSV100819839; called by muse, mutect2, varscan2
- PIDD1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as rs756216117, COSV61703946; called by muse, mutect2, varscan2
- PIGO | c.1924C>A p.P642T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as COSV99956975; called by muse, mutect2, varscan2
- PIGU | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs757521315, COSV99466060; called by muse, mutect2, varscan2
- PITPNM1 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs201501265, COSV62707327; called by muse, mutect2, varscan2
- PJA2 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV100754551, COSV63272571; called by muse, mutect2, varscan2
- PKD1 | c.10937T>C p.V3646A (on ENST00000262304 / NM_001009944.3; = p.V3645A on NM_000296.4) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99239104; called by muse, mutect2, varscan2
- PKD1 | c.4339G>A p.A1447T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs535676910, COSV99239106; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKHD1 | c.8344G>T p.G2782W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100584675; called by muse, mutect2, varscan2
- PKN1 | c.1477A>T p.I493F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV99661895; called by muse, mutect2, varscan2
- PKN2 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV60130702; called by muse, mutect2, varscan2
- PLAGL1 | c.899A>G p.N300S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.031); catalogued as COSV99394720; called by muse, mutect2, varscan2
- PLB1 | c.3132T>C p.N1044= | Splice Region (SNP) | VAF 17/56 reads (30%) | catalogued as rs201037347, COSV100579977; called by muse, mutect2, varscan2
- PLCG2 | c.1813C>A p.L605I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV100842678; called by muse, mutect2, varscan2
- PLCH1 | c.3379G>A p.V1127I (on ENST00000340059 / NM_001130960.2; = p.V1119I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs770825552, COSV100398333; called by muse, mutect2, varscan2
- PLCH2 | c.1455G>T p.E485D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as COSV99617206; called by muse, mutect2, varscan2
- PLEC | c.10733C>T p.S3578L (on ENST00000322810 / NM_201380.4; = p.S3468L on NM_000445.5) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs782569204, COSV59698097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.1978C>T p.R660C (on ENST00000322810 / NM_201380.4; = p.R550C on NM_000445.5) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1554718496, COSV59641941; called by muse, mutect2, varscan2
- PLEKHA3 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs756364278, COSV52297268; called by muse, mutect2, varscan2
- PLEKHG5 | c.2632C>T p.P878S (on ENST00000400915 / NM_001042663.3; = p.P841S on NM_020631.6) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.236); catalogued as COSV100557179; called by muse, mutect2, varscan2
- PLEKHO1 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs368658506, COSV99215439; called by muse, mutect2, varscan2
- PLK1 | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.11); catalogued as rs757326389, COSV99892435; called by muse, mutect2, varscan2
- PLK1 | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs755512074, COSV99892437; called by muse, mutect2, varscan2
- PLRG1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1007095919, COSV100123272; called by muse, mutect2, varscan2
- PLXDC1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs200381999, COSV59553956; called by muse, mutect2
- PLXDC2 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as COSV101023297; called by muse, mutect2, varscan2
- PLXNA2 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs750345311, COSV65437952; called by muse, mutect2, varscan2
- PLXNA4 | c.2888G>A p.R963Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.093); catalogued as rs374103757, COSV58122251; called by muse, mutect2, varscan2
- PLXNB3 | c.5173G>A p.V1725I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.16); catalogued as rs781971067, COSV100737957, COSV62798339; called by muse, mutect2
- PLXND1 | c.2180G>A p.C727Y | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100140448; called by muse, mutect2
- POGZ | c.3931G>A p.V1311I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as rs755307314, COSV99305315; called by muse, mutect2, varscan2
- POGZ | c.1762A>G p.M588V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99653259; called by muse, mutect2, varscan2
- POLD1 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99570165; called by muse, mutect2, varscan2
- POLDIP3 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV99349393; called by muse, mutect2, varscan2
- POLE | c.3028G>A p.A1010T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100268372; called by muse, mutect2, varscan2
- POLR3A | c.3234G>T p.K1078N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100965807; called by muse, mutect2, varscan2
- POLR3B | c.2560G>T p.V854L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV99943885; called by muse, mutect2, varscan2
- POMGNT2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs778907895, COSV100768157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPID | c.701dup p.K235Qfs*10 | Frame Shift Ins (INS) | VAF 34/162 reads (21%) | catalogued as rs766208165; called by mutect2, pindel, varscan2
- PPIL2 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs750545064, COSV58606992; called by muse, mutect2, varscan2
- PPM1F | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1194903845, COSV54282633; called by muse, mutect2, varscan2
- PPM1G | c.915T>A p.D305E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100085413; called by muse, mutect2, varscan2
- PPP1R10 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs748872079, COSV64739717; called by muse, mutect2, varscan2
- PPP1R26 | c.2672G>A p.R891H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs368489615; called by muse, mutect2, varscan2
- PPP2R2C | c.1092G>A p.M364I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as COSV100160951; called by muse, mutect2, varscan2
- PPP3CC | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as rs371119915; called by muse, mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs768056539; called by mutect2, varscan2
- PRAG1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs753931513, COSV100422879; called by muse, mutect2, varscan2
- PRAMEF12 | c.1097G>A p.S366N | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV100743612; called by muse, mutect2, varscan2
902 further variants in this file (412 protein-altering or splice-affecting, 457 silent, 33 other) are not listed here.
